Somatic mutation profile of tumor specimen TCGA-CQ-7065-01A (aliquot TCGA-CQ-7065-01A-11D-2078-08) from TCGA case TCGA-CQ-7065, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 40.2 years (14,676 days).
Specimen TCGA-CQ-7065-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65de944f-fbbd-4445-8c21-37bb8ab1bfab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-7065-10A (Blood Derived Normal), aliquot TCGA-CQ-7065-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89f0727e-3392-480e-aad8-9c0f15c9123c

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 21, Silent 8, Frame Shift Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>C p.H179P | Missense Mutation (SNP) | VAF 18/59 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C1orf159 | c.580G>A p.A194T (on ENST00000379339 / NM_001330306.2; = p.A158T on NM_017891.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99618416; called by muse, mutect2, varscan2
- CWC22 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV99844253; called by muse, mutect2, varscan2
- EPHB4 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs557044427, COSV100639497; called by muse, varscan2
- FRY | c.4237T>C p.S1413P | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); catalogued as COSV100969240; called by muse, mutect2, varscan2
- G6PD | c.478A>C p.S160R | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100855025; called by muse, mutect2, varscan2
- ITGA7 | c.3331C>T p.R1111W (on ENST00000555728; = p.R1067W on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs367574217; called by muse, mutect2, varscan2
- LRP1B | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs1379294814, COSV67196367; called by muse, mutect2, varscan2
- MAGEB2 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 31/38 reads (82%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs746022879, COSV66780608; called by muse, mutect2, varscan2
- MAGEC3 | c.1904T>C p.V635A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV100025355; called by muse, mutect2, varscan2
- MFN1 | c.432T>A p.H144Q | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54939688, COSV99764431; called by muse, mutect2, varscan2
- MUC16 | c.6722C>A p.S2241* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV101199869; called by muse, mutect2, varscan2
- NEMF | c.2789G>A p.R930K | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100027636; called by muse, mutect2, varscan2
- PPP4C | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV99661641; called by muse, mutect2, varscan2
- SCN2A | c.4885C>T p.R1629C | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51843815; called by muse, mutect2, varscan2
- SLC25A22 | c.937T>C p.S313P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV100204192; called by muse, mutect2, varscan2
- SLC47A1 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99565297; called by muse, mutect2, varscan2
- SLC8A1 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100245977; called by muse, mutect2, varscan2
- SLIT2 | c.2219G>A p.C740Y | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1443448116, COSV99883680; called by muse, mutect2, varscan2
- TFRC | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs781649382, COSV100786461; called by muse, mutect2, varscan2
- TTN | c.16114G>T p.D5372Y (on ENST00000591111; = p.D4445Y on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/143 reads (29%) | PolyPhen possibly damaging (0.742); catalogued as COSV100611782, COSV60158899; called by muse, mutect2, varscan2
- KRT5 | c.902dup p.N301Kfs*8 | Frame Shift Ins (INS) | VAF 35/120 reads (29%) | called by mutect2, pindel, varscan2
- PCDH17 | c.122A>C p.D41A | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBP3 | c.3314del p.P1105Qfs*25 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- ARHGAP9 | c.762T>A p.P254= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100712439; called by muse, varscan2
- CEP120 | c.1131G>A p.G377= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as COSV60267458; called by muse, mutect2
- HCAR3 | c.1158C>T p.I386= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as rs776811746, COSV100811591; called by muse, mutect2, varscan2
- IGFBP5 | c.456G>A p.V152= | Silent (SNP) | VAF 31/72 reads (43%) | catalogued as COSV99288924; called by muse, mutect2, varscan2
- KCNJ1 | c.84C>T p.V28= | Silent (SNP) | VAF 38/172 reads (22%) | catalogued as rs759301135, COSV60661970; called by muse, mutect2, varscan2
- KCNN2 | c.1440G>A p.V480= (on ENST00000264773; = p.V692= on NM_021614.4) | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99299736; called by muse, mutect2, varscan2
- OR4Q3 | c.648T>C p.S216= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100057012; called by muse, mutect2, varscan2
- PRNP | c.246A>G p.G82= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs62643364; ClinVar: benign; called by muse, varscan2
